Gene-level copy-number profile of tumor specimen ALCH-B1VP-TTP1-A from ALCHEMIST case ALCH-B1VP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,195 days).
Specimen ALCH-B1VP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4da30d12-8755-429d-bf2c-dfb592664d9d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/27ea6298-3415-4308-b856-28b31089768f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 540; copy number 1: 1,236; copy number 2: 32,333; copy number 3: 18,820; copy number 4: 3,370; copy number 5: 2,463; copy number 6: 76; copy number 7: 58; copy number 8: 1; copy number 9: 1; copy number 12: 4.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–2): AL512383.1.
- chr2:87,002,559–87,021,852, 1 gene (within-gene range 0–1): PLGLB1.
- chr4:184,254,509–184,625,030, 12 genes: AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362, IRF2, SNORD79, AC099343.2, IRF2-DT, LINC02427, AC099343.1, LINC02365.
- chr5:180,967,189–180,982,611, 3 genes: AC091874.2, AC091874.1, ARPP19P1.
- chr15:34,379,068–34,490,571, 6 genes (within-gene range 0–1): GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2.
- chr15:34,520,608–34,521,791, 1 gene: DNM1P5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,603 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–200,214,322, 1,440 genes, copy number 5 (broad region; genes not listed).
- chr1:200,315,435–200,315,967, 1 gene, copy number 5: AC097065.2.
- chr2:43,637,260–43,767,987, 3 genes, copy number 5 (within-gene range 5–6): PLEKHH2, C1GALT1C1L, AC011242.1.
- chr2:130,459,455–130,509,707, 2 genes, copy number 5: POTEI, RNU6-473P.
- chr2:242,175,181–242,175,634, 1 gene, copy number 7: RPL23AP88.
- chr5:58,198–45,895,970, 679 genes, copy number 5 (broad region; genes not listed).
- chr7:57,817,601–57,837,046, 8 genes, copy number 5: AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:74,773,962–74,789,376, 1 gene, copy number 9: NCF1.
- chr14:22,040,594–22,482,959, 48 genes, copy number 5–7: TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr14:27,258,717–28,968,400, 17 genes, copy number 5–7 (within-gene range 3–7): AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1.
- chr14:28,901,236–29,372,406, 2 genes, copy number 5 (within-gene range 3–5): Y_RNA, AL135878.1.
- chr14:29,210,986–31,861,224, 47 genes, copy number 5: AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P.
- chr14:32,074,946–32,203,269, 5 genes, copy number 5: ARHGAP5-AS1, ARHGAP5, AL161665.1, RNU6-7, RNU6-8.
- chr14:34,485,979–38,194,281, 89 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:46,839,629–48,046,216, 9 genes, copy number 5–7: MDGA2, AL359951.1, RPA2P1, RPL13AP2, RPS15AP3, MIR548Y, LINC00648, AL121576.1, AL359212.1.
- chr14:49,057,713–50,944,483, 64 genes, copy number 5 (broad region; genes not listed).
- chr14:51,750,560–52,010,694, 11 genes, copy number 5 (within-gene range 4–5): AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3, GNG2, AL358333.2, AL358333.3, AL358333.1, RTRAF.
- chr14:52,267,698–54,441,391, 34 genes, copy number 6–8: PTGDR, AL365475.1, PTGER2, TXNDC16, GPR137C, ERO1A, AL133453.1, PSMC6, STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4, AL352979.1, AL352979.3, DDHD1, AL352979.2, AL356020.1, AL365295.1, AL365295.2, AL163953.1, RPS3AP46, LINC02331, AL138479.1, MIR5580, BMP4, AL138479.2, ATP5F1CP1, CDKN3, CNIH1.
- chr14:55,496,786–62,152,258, 127 genes, copy number 5–6 (broad region; genes not listed).
- chr15:20,729,747–20,866,314, 9 genes, copy number 7–12: AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.1, MIR3118-2, POTEB2, RNU6-749P.
- chr16:90,102,271–90,178,344, 4 genes, copy number 5 (within-gene range 5–8): FAM157C, AC133919.1, AC133919.2, RNU6-355P.
- chr16:90,174,062–90,175,865, 1 gene, copy number 5: CICP25.

Autosomal genes at a single copy (total copy number 1): 1,191. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
